Surgical pathology report (de-identified scan), TCGA case TCGA-55-7227, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site International Genomics Consortium, specimen TCGA-55-7227-01A (Primary Tumor).

[page 1 of 4]
FINAL SURGICAL PATHOLOGY REPORT

Diagnosis:

A. LYMPH NODE, DESIGNATED "N8R", BIOPSY:

- FRAGMENTS OF ANTHRACOTIC LYMPH NODE.
- NEGATIVE FOR MALIGNANCY.

B. LUNG, RIGHT LOWER LOBE, LOBECTOMY:

- INVASIVE MODERATELY DIFFERENTIATED ADENOCARCINOMA OF THE LUNG, WITH VISCERAL PLEURAL INVASION.
- THE TUMOR MEASURES 62 MM IN DIAMETER.
- SATELLITE TUMOR NODULES PRESENT ADJACENT TO MAIN MASS.
- THE BRONCHIAL MARGIN IS FREE OF TUMOR.
- THE TUMOR IS PRESENT 50 MM FROM THE BRONCHIAL MARGIN.
- LUNG TISSUE WITH EMPHYSEMATOUS CHANGES AND RESPIRATORY BRONCHIOLITIS.
- METASTATIC CARCINOMA IN ONE OF THREE PERIBRONCHIAL LYMPH NODES (1/3).
- BENIGN GLANDULAR EPITHELIAL INCLUSION WITHIN PERIBRONCHIAL LYMPH NODE.
- FOCAL NONCASEATING, HYALINIZED GRANULOMATOUS INFLAMMATION WITHIN PERIBRONCHIAL LYMPH NODE.

C. LYMPH NODE, DESIGNATED "N9R", BIOPSY:

- ANTHRACOTIC LYMPH NODE.
- NEGATIVE FOR MALIGNANCY.
- SEE SYNOPTIC CANCER STAGING CHECKLIST.

COMMENT: Dr. [REDACTED] has co-reviewed representative slides from this case, and concurs with the diagnosis of adenocarcinoma.

[page 2 of 4]
FINAL SURGICAL PATHOLOGY REPORT

Lung Tumor Staging Information

(data derived from current specimen, staging in accordance with or modified from AJCC Cancer Staging Handbook, 7th Ed, and CAP protocol, [REDACTED])

Procedure:	Right lower lobectomy, with mediastinal lymph node biopsies.
TUMOR FEATURES:	
Tumor site:	Right lower lobe.
Tumor size:	62 mm.
Tumor focality:	Main tumor mass with at least 3 smaller satellite tumor nodules.
Histologic type:	Adenocarcinoma.
Histologic grade:	Moderately differentiated.
Lymphovascular invasion:	Present.
Visceral pleural invasion:	Present.
LYMPH NODES:	Two mediastinal lymph nodes submitted separately, without evidence of metastatic carcinoma. At least three peribronchial lymph nodes, one of which is involved by a small focus of metastatic carcinoma in the subcapsular sinus.
MARGINS:	
Bronchial margin:	Negative (tumor present 50 mm from bronchial margins).
Vascular margin:	Negative.
PATHOLOGIC TUMOR STAGING:	
Primary tumor:	pT3 (based on presence of separate satellite tumor nodules in the same lobe of lung).
Regional lymph nodes:	pN1 (metastasis in ipsilateral peribronchial lymph nodes).
Distant metastasis:	pMX (not applicable).
Pathologic stage:	IIIA.

[page 3 of 4]
FINAL SURGICAL PATHOLOGY REPORT

Source of Specimen:

- A. Lung bx
- B. Lung
- C. Lung bx

Clinical History/Operative Dx:

Malignant neoplasm, right lower lobe

Intraoperative Diagnosis:

B. Right lower lobe frozen section diagnosis: "Bronchial margin free of tumor". The intraoperative interpretation(s) was/were performed and rendered at

Gross Description:

A. The specimen is labeled N8R and is received in formalin. It consists of two 0.7 cm fragments of red-brown to anthracotic tissue. The specimens are inked with contrasting colors and each specimen is bisected. The tissue is entirely submitted in cassette A1.

B. The specimen is labeled right lower lobe and is received without fixative. It consists of a lobe of lung which measures 16.0 x 9.5 x 3.8 cm and weighs 269.0 grams. The pleural surface of the superior portion of the lobe has a mottled red to dark violet appearance and appears smooth. There is a prominent area of puckering and distortion of the lateral basilar portion of the lung. Adjacent to this pleural puckering and distortion are three subpleural firm prominent nodules which vary from 0.7 to 1.2 cm. There is another subpleural nodule in the lateral apical portion of the lung. At the hilum of the lung a staple line is dissected from the specimen and the bronchial margin is removed as a thin shave. There are three small up to 0.6 cm peribronchial lymph nodes. The bronchi are opened and there is no gross evidence of intraluminal tumor. Sections of the lateral basilar portion of the lung reveal a dull yellow relatively well circumscribed neoplasm which measures 6.2 x 5.0 x 2.9 cm. This neoplasm is 5.0 cm from the bronchial resection margin. It abuts and distorts the pleural surface. Representative sections are submitted. Sections summary: B1) bronchial margin from frozen section, B2) vascular margins, B3) peribronchial nodes, B4-B5) lateral basilar tumor and pleural surface, B6-B7) additional sections of tumor, B8) three subpleural nodules just adjacent to tumor, B9) subpleural node anterior apical lung, B10) uninvolved lung.

C. The specimen is labeled N9R and is received in formalin. It consists of a single 1.1 x 0.7 x 0.5 cm fragment of red-brown tissue. It is serially sectioned and entirely submitted in cassette C1.

Microscopic Description:

A. Microscopic sections have been examined. The microscopic findings are reflected in the diagnosis rendered.

[page 4 of 4]
FINAL SURGICAL PATHOLOGY REPORT

B. Special stain: Elastin stain, performed on blocks B5, B6, and B7, demonstrating visceral pleural invasion. Immunohistochemical stain: cytokeratin OSCAR, TTF-1, performed on block B3, demonstrating 1 mm metastatic focus within subcapsular sinus of peribronchial lymph node. The metastatic tumor and the epithelial inclusion stain positive for cytokeratin OSCAR, where as only the metastatic tumor stains positive for TTF-1. Appropriate positive and negative controls reviewed.

C. Microscopic sections have been examined. The microscopic findings are reflected in the diagnosis rendered.

Source: NCI Genomic Data Commons file c48861bd-0f32-479e-94ac-13002c070fa2 (TCGA-55-7227.7910979D-A635-4EF5-AB00-84DF0455DF66.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).